TCGA case TCGA-ER-A19M — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7a918706-c697-4cef-9661-346c5a612ff8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 36 years; Vital status: Dead; Days to death: 1,857 days (5.1 years).

Diagnoses (7)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.5; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Classification of tumor: Progression; Age at diagnosis: 39.1 years (14,287 days); Days to diagnosis: 987 days (2.7 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 36.4 years (13,300 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Interferon; Days to treatment start: 1,019 days (2.8 years); Days to treatment end: 1,093 days (3.0 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,079 days (3.0 years); Days to treatment end: 1,093 days (3.0 years); Treatment dose: 20 Gy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 1,169 days (3.2 years); Days to treatment end: 1,184 days (3.2 years); Treatment dose: 36 Gy; Treatment outcome: Progressive Disease; Treatment anatomic sites: Regional Site.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Extremities; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
4. Recurrence of diagnosis 2 (Malignant melanoma, NOS), site: Peripheral nerves and autonomic nervous system of upper limb and shoulder. Age at diagnosis: 39.6 years (14,452 days); Days to diagnosis: 1,152 days (3.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,165 days (3.2 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease.
5. Recurrence of diagnosis 2 (Malignant melanoma, NOS), site: Head, face or neck, NOS. Age at diagnosis: 39.9 years (14,580 days); Days to diagnosis: 1,280 days (3.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,287 days (3.5 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
6. Recurrence of diagnosis 2 (Malignant melanoma, NOS), site: Thorax, NOS. Age at diagnosis: 40.3 years (14,707 days); Days to diagnosis: 1,407 days (3.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,410 days (3.9 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.
7. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Jejunum. Age at diagnosis: 41.1 years (15,030 days); Days to diagnosis: 1,730 days (4.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,744 days (4.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (5 entries)
- Day 1,152 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Peripheral nerves and autonomic nervous system of upper limb and shoulder; Days to recurrence: 1,152 days (3.2 years).
- Day 1,280 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to recurrence: 1,280 days (3.5 years).
- Day 1,407 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 1,407 days (3.9 years).
- Day 1,730 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Jejunum; Days to progression: 1,730 days (4.7 years).
- Days to follow up: 1,857 days (5.1 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ER-A19M-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ER-A19M-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 390 mg.
  Slide TCGA-ER-A19M-06A-06-TSF: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ER-A19M-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 1.9; Primary melanoma tumor ulceration: No; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities.
- Drug treatment: Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,857 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,857 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,152 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ER-A19M-06A-61D-A238-01): tumor purity 0.51, ploidy 2.46, whole-genome doublings 1.
